Surgical pathology report (de-identified scan), TCGA case TCGA-32-1973, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1973-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Hemorrhagic brain tumor
2. Hemorrhagic brain tumor

GBM [REDACTED]
CONTROL [REDACTED]

CLINICAL DIAGNOSIS:

Hemorrhagic brain tumor

TCGA-32-1973

GROSS DESCRIPTION:

1. Received fresh for frozen section are multiple tan-pink to hemorrhagic soft tissue aggregating to 0.9 x 0.7 x 0.2 cm. A smear is performed. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

HIGH GRADE GLIOMA WITH ACUTE HEMORRHAGE. [REDACTED]

2. Received in formalin labeled with the patient's name and "hemorrhagic brain tumor permanent" are multiple fragments of tan-pink soft tissue aggregating to 2.4 x 0.8 x 0.3 cm. The specimen is entirely submitted in one cassette.

MICROSCOPIC DESCRIPTION:

1, 2. Sections demonstrate a glioblastoma characterized by a proliferation of glial cells which resemble astrocytes. The tumor cells exhibit elongated nuclei, prominent fibrillary processes and elongated nuclei. Occasional cells exhibit more bizarre nuclear features including multinucleation. Mitotic figures are readily identified. There is robust microvascular proliferation as well as necrosis. The neoplastic cells individually infiltrate the adjacent brain parenchyma. Scattered blood vessels demonstrate thrombosis and there is a background of acute hemorrhage. These histologic features are consistent with a glioblastoma.

DIAGNOSIS:

(PROVISIONAL):

- 1, 2. HEMORRHAGIC BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (WHO GRADE IV)

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Less than 10% of the neoplastic cells are immunoreactive for MGMT.

ADDENDUM DIAGNOSIS:

- 1, 2. HEMORRHAGIC BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (WHO GRADE IV)
- <10% IMMUNOREACTIVITY FOR MGMT.

Source: NCI Genomic Data Commons file d6f5fed4-33c9-4f0c-ba63-d9a5bd3291b5 (TCGA-32-1973.F22AD2E6-4EED-4538-A07B-365250184F02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).